MMRF case MMRF_2459 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6e823219-c3ad-4685-ae67-1b4812a74a4e

Demographics
Sex at birth: female; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.8 years (24,408 days); ISS stage: II; Days to last known disease status: 669 days (1.8 years); Days to last follow up: 669 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 82 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 136 days; Days to treatment end: 136 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 136 days; Days to treatment end: 136 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 606 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 606 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 1): M Protein 4.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 89.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 52.4 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.56 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.07 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.1 mmol/L; Albumin 31 g/L; Total Protein 9.8 g/dL; Glucose 10.4 mmol/L; C-Reactive Protein 1.02 mg/dL.
- Day 79: M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.91 µg/mL; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 9.79 mmol/L.
- Day 159 (ECOG 1): M Protein 0.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 3.19 µg/mL; Lactate Dehydrogenase 4.03 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.22 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.05 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 25 mmol/L.
- Day 236 (ECOG 0): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 3.62 µg/mL; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 2.44 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 10.8 mmol/L.
- Day 390 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.1 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 5.46 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 2.42 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.73 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 10.7 mmol/L.
- Day 436: Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.24 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 1.98 mmol/L; Albumin 34 g/L; Glucose 9.08 mmol/L.
- Day 548: M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.16 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.06 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 8 g/dL; Glucose 18.2 mmol/L.
- Day 606: Serum Free Immunoglobulin Light Chain, Kappa 10.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Hemoglobin 7.01 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.98 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Glucose 7.81 mmol/L.
- Day 669: M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.84 mg/dL; Hemoglobin 6.39 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 8.2 g/dL; Glucose 10.2 mmol/L.

Other clinical attributes
- Day -9: Weight: 48 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2459_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2459_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
